Surgical pathology report (de-identified scan), TCGA case TCGA-A2-A0CY, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Walter Reed, specimen TCGA-A2-A0CY-01A (Primary Tumor).

[page 1 of 4]
1CB-0-3

Carcinoma, infiltrating ductal, NOS 8500/3
Site, breast, NOS

C50.4

1/25/11

FOR OFFICIAL USE ONLY - PERSONAL DATA - PRIVACY ACT OF 1974

SURGICAL PATHOLOGY REPORT

Patient:
FMP/SSN:
DOB/Age/Sex:
Location:
Physician(s):

Race: WHITE

Specimen #:

Taken:
Received:
Reported:

SPECIMEN:

A: RIGHT BREAST B: LEFT BREAST C: SENTINEL LYMPH NODE #1
D: LEFT AXILLARY CONTENTS E: NON SENTINAL ,LT AXILLARY L.N.

FINAL DIAGNOSIS:

A. BREAST, RIGHT, MASTECTOMY:
- BENIGN BREAST TISSUE WITH FIBROCYSTIC CHANGES INCLUDING SCLEROSIS,
MICROCYST FORMATION, USUAL DUCTAL HYPERPLASIA, DUCT ECTASIA, AND
FOCAL MICROCALCIFICATION.

B. BREAST, LEFT, MASTECTOMY:
TUMOR TYPE: INVASIVE DUCTAL CARCINOMA.
NOTTINGHAM GRADE: III/III
NOTTINGHAM SCORE: 9/9

(Tubules= 3, Nuclei= 3, Mitoses= 3)
TUMOR SIZE (GREATEST DIMENSION OF INVASIVE COMPONENT): 3.5 CM
(MEASURED GROSSLY).

TUMOR NECROSIS: PRESENT.

VENOUS / LYMPHATIC INVASION: IDENTIFIED.

MARGINS:

- DISTANCE OF TUMOR FROM NEAREST MARGIN IS 0.4 CM, FROM THE
SUPERFICIAL LOWER OUTER QUADRANT (BLUE INK) MARGIN.
INTRADUCTAL COMPONENT: MULTIFOCAL, HIGH GRADE, SOLID AND COMEDO TYPE
EXTENDING WELL BEYOND THE INVASIVE COMPONENT.

LYMPH NODES: 1 OF 22 POSITIVE FOR TUMOR (PARTS C-E).

NIPPLE INVOLVEMENT: NOT IDENTIFIED.

SKIN INVOLVEMENT: NOT IDENTIFIED.

ESTROGEN RECEPTORS: POSITIVE (STRONG, >75% OF CELLS, FROM
PROGESTERONE RECEPTORS: NEGATIVE (WEAK, <5% OF CELLS, FROM
HER 2 NEU by IHC: NEGATIVE (1+ STAINING, FROM

PATHOLOGIC STAGE: pT2 N1 MX.

ADDITIONAL PATHOLOGIC CHANGES: FIBROCYSTIC CHANGES INCLUDING MICROCYST
FORMATION, DUCT ECTASIA, SCLEROIS, USUAL DUCTAL HYPERPLASIA, AND
FOCAL APOCRINE METAPLASIA.

C. LYMPH NODE, LEFT SENTINEL, EXCISION:

- ONE (1) LYMPH NODE NEGATIVE FOR METASTATIC CARCINOMA BY HEMATOXYLIN
AND EOSIN AND IMMUNOHISTOCHEMICAL (CYTOKERATIN) STAINS.

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

Patient:

Specimen #:

FINAL DIAGNOSIS (continued):

- D. LYMPH NODE, LEFT AXILLA, EXCISION:
- TWENTY (20) LYMPH NODES NEGATIVE FOR METASTATIC CARCINOMA.
- E. LYMPH NODE, LEFT NON-SENTINEL, EXCISION:
- ONE (1) LYMPH NODE POSITIVE FOR METASTATIC CARCINOMA.

COMMENT:

In specimen "E" the frozen section diagnosis of metastatic carcinoma is confirmed on the permanent sections.

**** Report Electronically Signed Out ****

=====

CLINICAL DIAGNOSIS AND HISTORY:

year old white female with history of left breast cancer

FROZEN SECTION DIAGNOSIS:

SPECIMEN TYPE:LYMPH NODE (SPECIMEN "E").

TIME RECEIVED:

TIME REPORTED:

REPORTED TO:

REPORTED BY

AND

BLOCKS: 1

SCRAPE PREPS:1

FROZEN SECTION DIAGNOSIS:POSITIVE FOR METASTATIC CARCINOMA.

GROSS DESCRIPTION:

A. Received in fresh labeled with the patient's name labeled "RIGHT BREAST SHORT STITCH SUPERIOR, LONG STITCH LATERAL" consists of a 927 gram mastectomy specimen oriented with a short stitch superior and long lateral. The specimen measures 24 cm medial to lateral, 19 cm superior to inferior, and 5 cm anterior to posterior. The lightly pigmented superficial skin ellipse measures 17 x 11.5 cm and displays a 1.0 cm centrally located everted nipple. No discharge or scar is noted. The deep margin is inked in black. Serial sections reveal lobulated yellow tan adipose tissue admixed with 10% moderately dense tan white fibrous tissue. The fibrous tissue is predominantly centrally located and shows catted blue grey cysts measuring up to 0.4 cm in greatest dimension. No

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

Patient:

Specimen #:

GROSS DESCRIPTION (continued):

discrete mass or lesion identified. No lymph nodes are identified.
Cassette summary:

- A1: skin
- A2: central
- A3: upper outer quadrant
- A4: lower outer quadrant
- A5: lower inner quadrant
- A6: upper inner quadrant
- A7: upper outer quadrant
- A8: lower outer quadrant
- A9: lower inner quadrant
- A10: upper inner quadrant
- A11: representative section of nipple.
- Matched sections of A1-A6 are submitted in OCT for CBCP protocol.

B. Received fresh labeled with the patient's name designated "LEFT BREAST SHORT STITCH SUPERIOR, LONG LATERAL" is a 954 gram mastectomy specimen oriented with a short stitch superior and long lateral. The specimen measures 24 cm medial to lateral, 18 cm superior to inferior, and 6 cm anterior to posterior. The lightly pigmented superficial skin ellipse measures 19 x 12.5 cm and displays a medially located 1.5 cm everted nipple free of discharge. No scar is noted. The deep margin is inked black and the superficial lower outer quadrant is inked blue. Serial sections reveal 3.5 x 3.2 x 2.8 cm well defined lobulated pink white indurated mass with focal hemorrhage. The mass is located within the lower outer quadrant and comes within 3.5 cm of the deep margin and 0.4 cm of the inked superficial surface. The remainder of the specimen is composed of approximately 50% dense tan white fibrous tissue which is diffusely nodular and focally cystic. The admixed adipose tissue is unremarkable. No additional masses are identified. No lymph nodes identified. Cassette summary:

- B1: skin
- B2: lower outer quadrant mass
- B3: lower outer quadrant
- B4: upper outer quadrant
- B5: upper inner quadrant
- B6: lower inner quadrant
- B7: representative section of closest deep margin
- B8-B9: representative sections of mass with closest point of approach to blue ink margin
- 10: representative section of nipple. 10CF

[page 4 of 4]
SURGICAL PATHOLOGY REPORT

Patient:

Specimen #:

GROSS DESCRIPTION (continued):

C. Received fresh labeled with the patient's name designated "SENTINEL LYMPH NODE #1" consists of a 2.0 x 1.7 x 1.0 cm pink yellow fatty lymph node. The specimen is trisected. Two thirds of the lymph node are placed in cassette C1 and C2. Matched section of C1 is placed in for CBCP protocol.

D. Received fresh labeled with the patient's name designated "LEFT AXILLARY CONTENTS" consists of an unoriented irregular portion of adipose tissue measuring 9.0 x 9.0 x 2.0 cm. Sectioning reveals multiple pink yellow fatty lymph nodes ranging in size from 0.4 to 2.4 cm in greatest dimension. Cassette summary:

- D1-D3: one lymph node each
- D4-D7: one lymph node bisected
- D8: two lymph nodes bisected, one inked black
- D9: four intact lymph nodes
- D10: one lymph node bisected
- D11: two lymph nodes
- D12: four possible lymph nodes. 12CF

E. Received fresh labeled with the patient's name designated "NON SENTINEL CLINICALLY SUSPICIOUS LEFT AXILLARY LYMPH NODE" consists of a 1.7 x 1.5 x 1.3 cm lymph node. Cut surface is homogeneous and firm. A portion is submitted for frozen section. 1C1

Source: NCI Genomic Data Commons file ebbf5a13-006e-4758-b147-bf00165a1392 (TCGA-A2-A0CY.CB780DE7-E98C-4F7E-9487-8F25FE80DC21.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).